Somatic mutation profile of tumor specimen TCGA-61-1728-01A (aliquot TCGA-61-1728-01A-01W-0699-08) from TCGA case TCGA-61-1728, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 59.1 years (21,582 days).
Specimen TCGA-61-1728-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b57c2b4-87d3-479d-879a-b254a1ae20ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-1728-11A (Solid Tissue Normal), aliquot TCGA-61-1728-11A-01W-0700-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30607efa-ae1c-4a00-adae-6374355b7812

The open-access MAF lists 55 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 14, Nonsense Mutation 3, In Frame Del 2, Intron 1, Frame Shift Del 1, Translation Start Site 1, 3'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 51/56 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY1 | c.1252G>A p.V418M | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749480692, COSV52031461; called by muse, mutect2, varscan2
- AGBL1 | c.2930T>C p.M977T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as rs746764320, COSV66856495; called by muse, mutect2, varscan2
- ATG101 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.191); catalogued as COSV61085133; called by muse, varscan2
- BCS1L | c.836T>C p.V279A | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV55309403; called by muse, mutect2
- BTN1A1 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 9/245 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.086); catalogued as COSV99764571; called by muse, mutect2
- CAPN9 | c.1633G>A p.V545I | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55233003; called by muse, mutect2, varscan2
- CASS4 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 67/384 reads (17%) | catalogued as COSV64386223; called by muse, mutect2, varscan2
- COL25A1 | c.1290C>G p.D430E | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV67649555; called by muse, mutect2, varscan2
- DCAF12L2 | c.575G>A p.G192D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100758867; called by muse, varscan2
- DNAJB5 | c.847A>C p.I283L | Missense Mutation (SNP) | VAF 37/433 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56625377; called by muse, mutect2
- FLG | c.8739A>C p.R2913S | Missense Mutation (SNP) | VAF 186/908 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as COSV64240935; called by muse, mutect2, varscan2
- FRMPD3 | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1268952183, COSV99347141; called by muse, varscan2
- FUT9 | c.633A>C p.K211N | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.919); catalogued as COSV56146039; called by muse, mutect2, varscan2
- GPR119 | c.856G>T p.V286L | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as COSV52275572; called by muse, mutect2, varscan2
- H3C8 | c.266C>A p.A89E | Missense Mutation (SNP) | VAF 22/326 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100010011; called by muse, mutect2
- H4C12 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.019); catalogued as rs756056656, COSV62743668, COSV62743967; called by mutect2, varscan2
- KCNK10 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100069370; called by muse, mutect2, varscan2
- KIRREL1 | c.709G>A p.G237S | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100780131; called by muse, mutect2
- LZTS3 | c.542dup p.Q182Afs*7 | Frame Shift Ins (INS) | VAF 4/24 reads (17%) | catalogued as rs745647523; called by pindel, varscan2
- MAP1B | c.2113C>T p.P705S | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as rs1358542538, COSV99702972; called by muse, mutect2, varscan2
- MAST4 | c.4547G>A p.R1516Q (on ENST00000403625 / NM_001164664.2; = p.R1327Q on NM_015183.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55123234; called by muse, mutect2, varscan2
- NR2C1 | c.1325G>C p.W442S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100280687; called by muse, mutect2
- NUMBL | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.728); catalogued as rs765466629, COSV53285144; called by muse, mutect2, varscan2
- OR10H1 | c.29C>G p.T10S | Missense Mutation (SNP) | VAF 62/391 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV58471321; called by muse, mutect2, varscan2
- PRSS16 | c.1300C>G p.P434A | Missense Mutation (SNP) | VAF 97/313 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV100041490, COSV57915380, COSV57917298; called by muse, mutect2, varscan2
- RAB28 | c.584A>C p.K195T | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs766709447, COSV56539120; called by muse, mutect2
- RPGRIP1 | c.3508G>A p.E1170K | Missense Mutation (SNP) | VAF 164/1372 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as COSV52849150; called by muse, mutect2, varscan2
- SHARPIN | c.1055G>A p.W352* | Nonsense Mutation (SNP) | VAF 18/79 reads (23%) | catalogued as COSV59644276; called by muse, mutect2, varscan2
- SPATA46 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs1173866712, COSV62634296; called by muse, mutect2, varscan2
- SZT2 | c.2390G>A p.R797H | Missense Mutation (SNP) | VAF 20/371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369282204, COSV100986849; called by muse, mutect2
- TBX10 | c.549+1G>T p.X183_splice | Splice Site (SNP) | VAF 22/53 reads (42%) | catalogued as rs775096048, COSV56875260, COSV56875516; called by muse, mutect2, varscan2
- TNFRSF11B | c.956G>T p.C319F | Missense Mutation (SNP) | VAF 20/474 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99817010; called by muse, mutect2
- TTC14 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 39/237 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV56010753; called by muse, mutect2, varscan2
- CHRNE | c.742_744del p.I248del | In Frame Del (DEL) | VAF 18/54 reads (33%) | called by pindel, varscan2
- DDIAS | c.617_622del p.A206_L207del | In Frame Del (DEL) | VAF 132/664 reads (20%) | called by mutect2, varscan2
- IGLV2-33 | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 36/924 reads (4%) | called by muse, mutect2
- NNT | c.514del p.T172Lfs*21 | Frame Shift Del (DEL) | VAF 237/437 reads (54%) | called by mutect2, pindel, varscan2
- TBX19 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 30/260 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.365); called by mutect2, varscan2
- ALS2 | c.2484G>A p.Q828= | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as COSV51886567; called by muse, mutect2, varscan2
- BEND2 | c.192T>C p.F64= | Silent (SNP) | VAF 15/330 reads (5%) | catalogued as COSV101192230; called by muse, mutect2
- CALML4 | c.105C>T p.P35= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV99992735; called by muse, mutect2, varscan2
- DMBT1 | c.1524G>A p.E508= | Silent (SNP) | VAF 29/919 reads (3%) | catalogued as COSV100354165; called by muse, mutect2
- G6PC3 | c.549C>T p.G183= | Silent (SNP) | VAF 73/85 reads (86%) | catalogued as COSV52242443; called by muse, mutect2, varscan2
- OR51A4 | c.276T>G p.P92= | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as COSV100985375; called by muse, mutect2
- PRPF8 | c.4719C>T p.L1573= | Silent (SNP) | VAF 143/361 reads (40%) | catalogued as COSV59262990; called by muse, mutect2, varscan2
- SHANK2 | c.2457A>G p.Q819= | Silent (SNP) | VAF 7/107 reads (7%) | catalogued as COSV99573395, COSV99576246; called by muse, mutect2
- SP3 | c.648C>T p.A216= | Silent (SNP) | VAF 60/428 reads (14%) | catalogued as rs1419090940, COSV59467373; called by muse, varscan2
- TET2 | c.1224C>A p.P408= | Silent (SNP) | VAF 32/292 reads (11%) | catalogued as COSV99484954; called by muse, mutect2
- THBD | c.1362G>A p.V454= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV65702318; called by muse, mutect2, varscan2
- TXK | c.714C>T p.L238= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV99972879; called by muse, mutect2, varscan2
- UBE2L6 | c.97C>T p.L33= | Silent (SNP) | VAF 74/471 reads (16%) | catalogued as COSV54702896; called by muse, mutect2, varscan2
- VSTM2A | c.123G>T p.G41= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV56493483; called by muse, mutect2, varscan2
- C1QTNF3 | c.84+114G>A | Intron (SNP) | VAF 90/1488 reads (6%) | catalogued as rs767994826, COSV99180735; called by muse, mutect2
- MFSD4B | c.*241C>T | 3'UTR (SNP) | VAF 26/89 reads (29%) | catalogued as COSV64348811; called by muse, mutect2, varscan2
